Somatic mutation profile of tumor specimen TARGET-10-PARMKM-03A (aliquot TARGET-10-PARMKM-03A-01D) from TARGET case TARGET-10-PARMKM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (581 days).
Specimen TARGET-10-PARMKM-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b0992fa-8166-4815-a633-0930ece9cfd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARMKM-14A (Bone Marrow Normal), aliquot TARGET-10-PARMKM-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93e6d4be-aa68-4be7-8f09-4a1a07e88508

The open-access MAF lists 18 somatic variants for this specimen: 10 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 7, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.6140C>T p.A2047V (on ENST00000272895 / NM_173076.3; = p.A1729V on NM_015657.3) | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs755491703, COSV55964787; called by muse, mutect2, varscan2
- BCL11B | c.1415G>A p.R472H (on ENST00000357195 / NM_001282237.2; = p.R401H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1231938148, COSV61734054; called by muse, mutect2
- COL4A4 | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as COSV61633655; called by muse, mutect2, varscan2
- DACH2 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs745838015, COSV64173915; called by muse, mutect2, varscan2
- EMILIN3 | c.2230C>A p.R744S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as COSV60037085; called by muse, mutect2, varscan2
- FOXS1 | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV54066971; called by muse, mutect2, varscan2
- PTEN | c.696_697insTCGAACGT p.R233Sfs*26 | Frame Shift Ins (INS) | VAF 16/98 reads (16%) | catalogued as COSV64288717, COSV64289856, COSV64298421, COSV64299115, COSV64306382, COSV64307526, COSV99058011, COSV99058016, COSV99058020; called by pindel, varscan2
- TMC4 | c.925G>A p.V309M (on ENST00000617472 / NM_001145303.3; = p.V303M on NM_144686.4) | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56600826; called by muse, mutect2, varscan2
- ZGLP1 | c.311C>A p.T104N | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV58533379; called by muse, mutect2, varscan2
- MUC21 | c.899C>A p.A300D | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- AGTR2 | c.834G>A p.L278= | Silent (SNP) | VAF 21/235 reads (9%) | catalogued as rs782239815; called by muse, mutect2
- CCDC166 | c.1008G>A p.S336= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs937767594; called by muse, mutect2
- ESR1 | c.102C>A p.P34= | Silent (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- ETV3 | c.1404A>T p.A468= | Silent (SNP) | VAF 17/152 reads (11%) | called by muse, mutect2
- GAS2L1 | c.1839G>C p.G613= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as rs749827785, COSV53329914; called by muse, mutect2, varscan2
- OR51C1P | c.846G>T p.L282= | Silent (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- ZNF786 | c.1152C>T p.L384= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1180674983; called by muse, mutect2, varscan2
- TMEM87A | c.1063-627T>C | Intron (SNP) | VAF 45/106 reads (42%) | catalogued as COSV67747280; called by muse, mutect2, varscan2
